Somatic mutation profile of tumor specimen TCGA-86-8585-01A (aliquot TCGA-86-8585-01A-11D-2393-08) from TCGA case TCGA-86-8585, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 57.3 years (20,918 days).
Specimen TCGA-86-8585-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29705d55-0d2a-445e-9ecf-0b91e48d9c79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8585-10A (Blood Derived Normal), aliquot TCGA-86-8585-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f56b0c73-f6b2-4c84-84f2-d2f3e817da7c

The open-access MAF lists 620 somatic variants for this specimen: 490 protein-altering or splice-affecting, 117 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 417, Silent 117, Nonsense Mutation 24, Frame Shift Del 19, Splice Site 14, Splice Region 6, Frame Shift Ins 5, Translation Start Site 4, RNA 4, Intron 4, 3'UTR 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4416G>T p.W1472C | Missense Mutation (SNP) | VAF 26/151 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52117493; called by muse, mutect2, varscan2
- A2ML1 | c.1886A>T p.E629V | Missense Mutation (SNP) | VAF 110/375 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100228539, COSV100229633; called by muse, mutect2, varscan2
- ABCA2 | c.7231C>T p.Q2411* (on ENST00000614293; = p.Q2381* on NM_001606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as rs1219251484, COSV99686924; called by muse, mutect2
- ABCA2 | c.5302C>G p.H1768D (on ENST00000614293; = p.H1738D on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99686926; called by muse, mutect2, varscan2
- ABCA7 | c.5120A>G p.Q1707R | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV99565176; called by muse, mutect2
- ABCB1 | c.1366C>A p.Q456K | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.621); catalogued as COSV55958000, COSV99712174; called by muse, mutect2, varscan2
- ABCC1 | c.3205A>T p.S1069C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100578590; called by muse, mutect2, varscan2
- ABCG2 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 69/227 reads (30%) | catalogued as COSV99418526; called by muse, mutect2, varscan2
- ABL2 | c.293A>T p.K98M (on ENST00000502732 / NM_007314.4; = p.K83M on NM_005158.5) | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100772467; called by muse, mutect2, varscan2
- ABRA | c.214C>A p.H72N | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as COSV100357468; called by muse, mutect2, varscan2
- ACAD10 | c.2382G>A p.M794I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV100563826; called by muse, mutect2, varscan2
- ACBD5 | c.693G>T p.L231F (on ENST00000375888 / NM_001352568.1; = p.L222F on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.965); catalogued as COSV65518084; called by muse, mutect2, varscan2
- ACP3 | c.123G>A p.V41= | Splice Region (SNP) | VAF 21/77 reads (27%) | catalogued as rs757622848, COSV100313124; called by muse, mutect2, varscan2
- ACSM3 | c.386G>C p.R129T | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99184050; called by muse, mutect2, varscan2
- ADAM12 | c.2600C>A p.T867N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV100902972; called by muse, mutect2, varscan2
- ADAMTS12 | c.3201G>A p.W1067* | Nonsense Mutation (SNP) | VAF 18/148 reads (12%) | catalogued as rs779600276, COSV100710299; called by muse, mutect2, varscan2
- ADCY8 | c.2237C>G p.S746C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV53928925, COSV99650809; called by muse, mutect2, varscan2
- ADGRB3 | c.2820C>G p.I940M | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.522); catalogued as COSV99483690; called by muse, mutect2, varscan2
- AGTR2 | c.48C>A p.S16R | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100903533, COSV64157031; called by muse, mutect2, varscan2
- AGXT2 | c.561C>A p.N187K | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.486); catalogued as COSV99183705; called by muse, mutect2, varscan2
- AHRR | c.1736G>T p.R579L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs761404483, COSV100326641; called by muse, mutect2, varscan2
- ALKBH5 | c.397T>G p.Y133D | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99231226; called by muse, mutect2, varscan2
- AMACR | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100162814; called by muse, mutect2, varscan2
- ANAPC5 | c.2074G>T p.E692* | Nonsense Mutation (SNP) | VAF 40/158 reads (25%) | catalogued as COSV99945945; called by muse, varscan2
- ANGPT2 | c.529C>A p.Q177K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100290604; called by muse, mutect2, varscan2
- ANKRD30A | c.3892G>A p.A1298T (on ENST00000611781; = p.A1242T on NM_052997.2) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs374582792, COSV100652952; called by muse, mutect2, varscan2
- APLP1 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99697498; called by muse, mutect2, varscan2
- ARAP2 | c.3437G>C p.C1146S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100394134; called by muse, mutect2, varscan2
- ARHGAP18 | c.1839-1G>T p.X613_splice | Splice Site (SNP) | VAF 22/78 reads (28%) | catalogued as COSV100936017; called by muse, mutect2, varscan2
- ARID4A | c.1027C>G p.L343V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1279696057, COSV100794023; called by muse, mutect2, varscan2
- ARSH | c.1054G>C p.G352R | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101139746; called by muse, mutect2, varscan2
- ASAH1 | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.203); catalogued as COSV50504126; called by muse, mutect2
- ASB4 | c.74T>A p.L25Q | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99987103; called by muse, mutect2
- ASB5 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0.182); catalogued as rs148482187; called by muse, mutect2, varscan2
- ATAD2B | c.3595G>A p.G1199R | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as COSV99476991; called by muse, mutect2, varscan2
- ATG5 | c.128G>T p.S43I | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100576390; called by muse, mutect2, varscan2
- ATOH1 | c.772C>A p.Q258K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV100024430; called by muse, mutect2, varscan2
- ATP10A | c.1264C>A p.Q422K | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100790884, COSV63513344; called by muse, mutect2, varscan2
- ATP6V0D2 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.181); catalogued as rs536707158, COSV99571336; called by muse, mutect2, varscan2
- ATP7A | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV100430266; called by muse, mutect2, varscan2
- ATXN1 | c.401A>T p.Q134L | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV99785056; called by muse, mutect2, varscan2
- BBX | c.1546A>T p.S516C | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV100361057; called by muse, mutect2, varscan2
- BBX | c.1547G>A p.S516N | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100361059; called by muse, mutect2, varscan2
- BEND3 | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 85/147 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV100944543, COSV64682410; called by muse, mutect2, varscan2
- BLM | c.571A>G p.R191G | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV100756941; called by muse, mutect2, varscan2
- BLM | c.3089G>T p.C1030F | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100756944; called by muse, mutect2
- BPIFC | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100300752; called by muse, mutect2, varscan2
- BRINP3 | c.539T>A p.L180Q | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100818369; called by muse, varscan2
- BSG | c.851A>G p.E284G | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100344498; called by muse, mutect2
- C10orf71 | c.1043C>A p.P348H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100109714; called by muse, mutect2, varscan2
- C9orf43 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99928198; called by muse, mutect2, varscan2
- CACNA1A | c.3376C>A p.R1126S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.193); catalogued as COSV100800976; called by muse, mutect2, varscan2
- CACNA2D1 | c.1396G>T p.V466F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100665907; called by muse, mutect2, varscan2
- CACNA2D4 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1225914710, COSV54956311, COSV99765058; called by muse, mutect2, varscan2
- CAD | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV99254389, COSV99254428; called by muse, mutect2, varscan2
- CALCR | c.427A>T p.K143* | Nonsense Mutation (SNP) | VAF 21/112 reads (19%) | catalogued as COSV100810412; called by muse, mutect2, varscan2
- CALN1 | c.430T>A p.F144I (on ENST00000329008 / NM_001017440.3; = p.F186I on NM_031468.4) | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100204953; called by muse, mutect2, varscan2
- CCDC102A | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 99/282 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV99264806; called by muse, mutect2, varscan2
- CCDC178 | c.1060T>C p.Y354H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV100283445; called by muse, mutect2, varscan2
- CD6 | c.1949C>A p.P650H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as rs1172012992, COSV100532807, COSV100533342; called by muse, mutect2, varscan2
- CDH10 | c.1516-1G>T p.X506_splice | Splice Site (SNP) | VAF 43/252 reads (17%) | catalogued as COSV52570414; called by muse, mutect2, varscan2
- CDIN1 | c.142T>G p.Y48D | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100589626; called by muse, mutect2
- CDKN2A | c.47T>A p.L16Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs864622263, CM023346, CM980321, COSV100445285, COSV58693684, COSV58729402; ClinVar: uncertain significance; called by muse, mutect2
- CDR1 | c.156G>T p.L52F | Missense Mutation (SNP) | VAF 73/156 reads (47%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as COSV65164704; called by muse, mutect2, varscan2
- CEP152 | c.2069G>T p.R690L | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs778066207, COSV100358461, COSV57860852; called by muse, mutect2, varscan2
- CEP72 | c.1633G>C p.D545H | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV99374475; called by muse, mutect2, varscan2
- CHD4 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 102/356 reads (29%) | catalogued as COSV100537405; called by muse, mutect2, varscan2
- CHD7 | c.6736G>T p.E2246* | Nonsense Mutation (SNP) | VAF 15/111 reads (14%) | catalogued as COSV101418002; called by muse, mutect2, varscan2
- CHEK2 | c.1286G>T p.G429V (on ENST00000382580 / NM_001005735.2; = p.G386V on NM_007194.4) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100101056; called by muse, mutect2, varscan2
- CHRM2 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 16/163 reads (10%) | catalogued as COSV100280759, COSV57768841; called by muse, mutect2, varscan2
- CHRM5 | c.941A>G p.K314R | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV101271837; called by muse, mutect2, varscan2
- CHRNA3 | c.1187C>A p.P396H | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.447); catalogued as rs1383872006, COSV100467860; called by muse, mutect2, varscan2
- CHST13 | c.434C>A p.A145E | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.33); PolyPhen benign (0.036); catalogued as COSV100080958, COSV60042104; called by muse, mutect2, varscan2
- CKM | c.725A>C p.K242T | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.909); catalogued as COSV99487885; called by muse, mutect2, varscan2
- CLCN7 | c.1160T>A p.V387E | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV99246903; called by muse, mutect2, varscan2
- CLUAP1 | c.185G>C p.R62P | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100489495, COSV58893999, COSV58894108; called by muse, mutect2, varscan2
- CLVS2 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.503); catalogued as COSV99252168; called by muse, mutect2, varscan2
- CNGA1 | c.919A>T p.I307F | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV100652122; called by muse, mutect2, varscan2
- COBL | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99471317; called by muse, mutect2, varscan2
- COL11A1 | c.4238C>A p.P1413H | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100615214; called by muse, mutect2, varscan2
- COL11A1 | c.1786G>T p.A596S | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV100615218, COSV62174846; called by muse, mutect2, varscan2
- COL14A1 | c.405A>C p.R135S | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99918078; called by muse, mutect2
- COL3A1 | c.4124G>T p.S1375I | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100482497; called by muse, mutect2, varscan2
- COL4A3 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381056489, COSV101169955; called by muse, mutect2, varscan2
- COL4A5 | c.2800C>G p.P934A | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.033); catalogued as COSV100086546, COSV60360799; called by muse, mutect2, varscan2
- COL7A1 | c.6146G>T p.G2049V | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM970379, COSV100095154; called by muse, mutect2, varscan2
- COP1 | c.679G>T p.G227* | Nonsense Mutation (SNP) | VAF 29/75 reads (39%) | catalogued as COSV100442766; called by muse, mutect2, varscan2
- CR2 | c.2098C>G p.Q700E | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV100889533; called by muse, mutect2, varscan2
- CSE1L | c.2585C>A p.T862N | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs775701351, COSV99521835; called by muse, mutect2, varscan2
- CSMD2 | c.3644G>A p.G1215E | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV53890052; called by muse, mutect2, varscan2
- CSMD3 | c.9962T>A p.F3321Y (on ENST00000297405 / NM_001363185.1; = p.F3152Y on NM_052900.3) | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as COSV99825317; called by muse, mutect2
- CSMD3 | c.7413C>A p.S2471R (on ENST00000297405 / NM_001363185.1; = p.S2367R on NM_052900.3) | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99825322; called by muse, mutect2, varscan2
- CSPG4 | c.2816G>T p.R939L | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs764298770, COSV100413430, COSV57897391; called by muse, mutect2, varscan2
- CSPG4 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV100413431; called by muse, mutect2, varscan2
- CTNNA2 | c.122C>A p.T41K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.506); catalogued as COSV100781809; called by muse, mutect2, varscan2
- CTNND1 | c.1138G>T p.D380Y | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100649806; called by muse, mutect2, varscan2
- CYP1B1 | c.950T>A p.L317* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99572578; called by muse, mutect2, varscan2
- CYP27C1 | c.953G>T p.C318F | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100079673; called by muse, mutect2, varscan2
- CYP51A1 | c.291G>C p.K97N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99133597; called by muse, mutect2
- CYSLTR2 | c.281G>T p.R94M | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319359208, COSV99935118; called by muse, mutect2, varscan2
- DBN1 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs142058925; called by muse, mutect2, varscan2
- DCAF4 | c.4A>T p.N2Y | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100610908; called by muse, mutect2, varscan2
- DCAF6 | c.891G>T p.E297D | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.551); catalogued as COSV100393944; called by muse, mutect2, varscan2
- DCHS1 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100201494; called by muse, mutect2, varscan2
- DCLK1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55214935; called by muse, mutect2, varscan2
- DDX24 | c.1067A>T p.N356I | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV100427817; called by muse, mutect2, varscan2
- DDX60L | c.2927A>T p.D976V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV99486964; called by muse, mutect2, varscan2
- DIDO1 | c.6180G>T p.E2060D | Missense Mutation (SNP) | VAF 55/303 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.528); catalogued as COSV99824762; called by muse, mutect2, varscan2
- DIO2 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101375818; called by muse, mutect2, varscan2
- DISP3 | c.1749G>T p.Q583H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99607384; called by muse, mutect2, varscan2
- DLAT | c.1225G>C p.G409R | Missense Mutation (SNP) | VAF 18/327 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as rs782098396, COSV99734414; called by muse, mutect2
- DLG2 | c.976A>G p.R326G | Missense Mutation (SNP) | VAF 63/244 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.232); catalogued as COSV99712751; called by muse, mutect2, varscan2
- DMBT1 | c.4984G>T p.V1662L (on ENST00000338354 / NM_001377530.1; = p.V905L on NM_004406.3) | Missense Mutation (SNP) | VAF 98/671 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100352123; called by muse, mutect2, varscan2
- DNAAF4 | c.293G>T p.R98I | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.235); catalogued as COSV100336585; called by muse, mutect2, varscan2
- DNAH11 | c.7501G>C p.E2501Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV100177242; called by muse, mutect2, varscan2
- DNAH5 | c.600G>T p.L200F | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV99445279; called by muse, mutect2, varscan2
- DNAJC5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100694138; called by muse, mutect2, varscan2
- DNTT | c.1437G>T p.K479N | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.886); catalogued as COSV100960435; called by muse, mutect2, varscan2
- DRICH1 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as rs775997324, COSV100497412, COSV100497428; called by muse, mutect2, varscan2
- DROSHA | c.2107C>G p.L703V | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100757450, COSV60778468; called by muse, mutect2
- DSP | c.525G>C p.Q175H | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65793201; called by muse, mutect2, varscan2
- DYNC2H1 | c.1465G>A p.V489I | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1237984178, COSV100517575; called by muse, mutect2
- EDNRB | c.1590C>G p.S530R (on ENST00000377211 / NM_001201397.1; = p.S440R on NM_000115.5) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.779); catalogued as COSV57519963; called by muse, mutect2, varscan2
- EMP3 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs1213645392, COSV99506944, COSV99506957; called by muse, mutect2, varscan2
- EMX2 | c.274_275insT p.H92Lfs*49 | Frame Shift Ins (INS) | VAF 16/61 reads (26%) | catalogued as COSV101463577; called by mutect2, pindel, varscan2
- EPHA5 | c.1403-1G>C p.X468_splice | Splice Site (SNP) | VAF 15/62 reads (24%) | catalogued as COSV99896303; called by muse, mutect2, varscan2
- EPRS1 | c.2583G>T p.K861N | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100859311; called by muse, mutect2, varscan2
- EPYC | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as COSV99664493; called by muse, mutect2, varscan2
- ESR1 | c.1180C>A p.R394S | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755020320, COSV52789083, COSV99237922; called by muse, mutect2, varscan2
- ESRRG | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.238); catalogued as rs370360195, COSV63173323; called by muse, mutect2, varscan2
- EXOC8 | c.1389C>G p.F463L | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99149468; called by muse, mutect2, varscan2
- FABP12 | c.71T>A p.L24Q | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100846567; called by muse, mutect2
- FAM120A | c.1166G>T p.G389V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.893); catalogued as COSV99464556; called by mutect2, varscan2
- FAM135B | c.1253C>G p.A418G | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs747666977, COSV99419121, COSV99425733; called by muse, mutect2, varscan2
- FAM135B | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs1266973180, COSV52705827; called by muse, mutect2, varscan2
- FAM47B | c.1280C>A p.P427H | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100264067; called by muse, mutect2, varscan2
- FAM47C | c.484G>C p.A162P | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV63724173, COSV63727538; called by muse, mutect2, varscan2
- FAM47C | c.1426C>G p.P476A | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV100792283, COSV100793002; called by muse, mutect2, varscan2
- FAM53B | c.237G>T p.W79C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99784816; called by muse, mutect2, varscan2
- FAT4 | c.7462T>A p.F2488I | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.465); catalogued as COSV100627259; called by muse, mutect2, varscan2
- FAT4 | c.12253G>C p.E4085Q | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100627260, COSV58682996; called by muse, mutect2
- FBN3 | c.1846G>T p.V616L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV54452729; called by muse, mutect2, varscan2
- FGF10 | c.326-1G>A p.X109_splice | Splice Site (SNP) | VAF 15/46 reads (33%) | catalogued as COSV99240099; called by muse, mutect2, varscan2
- FHDC1 | c.2272G>T p.G758C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.628); catalogued as COSV99471030; called by muse, mutect2, varscan2
- FLG2 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs189954307, COSV101165597; called by muse, mutect2, varscan2
- FLG2 | c.1150G>T p.G384W | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101165598; called by muse, mutect2, varscan2
- FLNB | c.4529A>G p.K1510R | Missense Mutation (SNP) | VAF 61/236 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as COSV99911829; called by muse, mutect2, varscan2
- FNIP2 | c.110G>T p.W37L | Missense Mutation (SNP) | VAF 61/268 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100032188; called by muse, mutect2, varscan2
- FNTA | c.884T>C p.L295P | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100172397, COSV56490844; called by muse, mutect2, varscan2
- FRMPD3 | c.2738C>G p.A913G | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV99345696; called by muse, mutect2, varscan2
- FUT3 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.159); catalogued as COSV100297180; called by muse, mutect2, varscan2
- FZD7 | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV99636836; called by muse, mutect2
- GAA | c.2500A>T p.T834S | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.218); catalogued as COSV100162938; called by muse, mutect2, varscan2
- GAB4 | c.956C>A p.T319N | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV101271885; called by muse, mutect2, varscan2
- GABPA | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100702341, COSV100702403; called by muse, mutect2, varscan2
- GADL1 | c.953T>G p.L318R | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99243781; called by muse, mutect2, varscan2
- GAK | c.2134A>G p.R712G | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV100033164; called by muse, mutect2, varscan2
- GCFC2 | c.1682G>T p.R561L | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV58080795; called by muse, mutect2, varscan2
- GDF6 | c.488G>C p.G163A | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV99747641; called by muse, varscan2
- GLCE | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1408010243, COSV99962087; called by muse, mutect2, varscan2
- GOLGB1 | c.5089G>A p.D1697N | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV100510350; called by muse, mutect2, varscan2
- GPATCH3 | c.337C>G p.Q113E | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1342717048, COSV64652862; called by muse, mutect2, varscan2
- GPATCH4 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 46/520 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV100576878; called by muse, mutect2
- GPR180 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1379978258, COSV100978993; called by muse, mutect2, varscan2
- GPRC5C | c.1137G>T p.Q379H (on ENST00000652232; = p.Q334H on NM_018653.4) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100702805; called by muse, mutect2, varscan2
- GRAMD1A | c.429G>T p.T143= | Splice Region (SNP) | VAF 33/135 reads (24%) | catalogued as COSV100525966; called by muse, mutect2, varscan2
- GRB14 | c.1383-1G>T p.X461_splice | Splice Site (SNP) | VAF 16/69 reads (23%) | catalogued as COSV55743259, COSV99813682; called by muse, mutect2, varscan2
- GRIN2A | c.215T>A p.L72Q | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV100408394; called by muse, mutect2, varscan2
- GRK3 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100151110; called by muse, mutect2, varscan2
- HCN1 | c.1369C>G p.L457V | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV100298680, COSV57505727; called by muse, mutect2, varscan2
- HCN2 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52119712; called by muse, mutect2, varscan2
- HDAC4 | c.503G>T p.S168I | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100612699, COSV61863425; called by muse, mutect2, varscan2
- HERC2 | c.1676G>A p.G559E | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99871088; called by muse, mutect2
- HHIPL2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100596617, COSV58564516; called by muse, mutect2
- HIP1R | c.1398A>T p.R466S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99458291; called by muse, mutect2, varscan2
- HMGN5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100814788, COSV100815013; called by muse, mutect2, varscan2
- ICE1 | c.2935G>T p.G979* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV99663809; called by muse, mutect2, varscan2
- IFNA8 | c.441C>G p.F147L | Missense Mutation (SNP) | VAF 101/345 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101206880; called by muse, mutect2, varscan2
- IFT46 | c.413C>G p.S138C (on ENST00000264021 / NM_001168618.2; = p.S189C on NM_020153.3) | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV99870898; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs781081739; called by muse, varscan2
- IGKV3-11 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762185728; called by muse, varscan2
- IL16 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100267003; called by muse, mutect2
- IL1RAPL1 | c.1677G>T p.M559I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100145206; called by muse, mutect2, varscan2
- IRX2 | c.1219C>A p.L407I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100121573; called by muse, mutect2, varscan2
- ITGA11 | c.2322G>A p.S774= | Splice Region (SNP) | VAF 13/91 reads (14%) | catalogued as rs778799202, COSV59881833; called by muse, mutect2, varscan2
- ITGB1 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100171253; called by muse, mutect2, varscan2
- ITM2A | c.480C>G p.C160W | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100964413; called by muse, mutect2, varscan2
- JADE3 | c.2314G>C p.E772Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99509548; called by muse, mutect2, varscan2
- JAG1 | c.3391del p.A1131Pfs*19 | Frame Shift Del (DEL) | VAF 17/106 reads (16%) | catalogued as COSV54755912; called by mutect2, pindel, varscan2
- KAT5 | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.217); catalogued as COSV100383818; called by muse, mutect2, varscan2
- KCNH1 | c.435T>G p.C145W | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as COSV99657387; called by muse, mutect2
- KCNJ8 | c.104G>C p.R35P | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99557377; called by muse, mutect2, varscan2
- KCNK9 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs771203947, COSV100270382, COSV57286353; called by muse, mutect2, varscan2
- KCNT2 | c.3308G>T p.R1103L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54075788, COSV99651618; called by muse, mutect2
- KDM6B | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99640757; called by muse, mutect2, varscan2
- KHSRP | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV101231131; called by muse, mutect2, varscan2
- KIAA0319 | c.2311G>T p.D771Y | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100985212; called by muse, mutect2, varscan2
- KIAA1109 | c.3321G>C p.K1107N | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs772064200, COSV99145872, COSV99151199; called by muse, mutect2
- KIAA1109 | c.5711-1G>C p.X1904_splice | Splice Site (SNP) | VAF 18/65 reads (28%) | catalogued as COSV99145875; called by muse, mutect2, varscan2
- KIF15 | c.4159G>C p.E1387Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.328); catalogued as COSV100392470, COSV58158904; called by muse, mutect2, varscan2
- KIF26B | c.4075G>A p.G1359S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1397029070, COSV100831639; called by muse, mutect2, varscan2
- KIF4B | c.1955G>T p.R652L | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV101469192, COSV70526998; called by muse, mutect2, varscan2
- KIR2DL1 | c.817del p.N273Mfs*4 | Frame Shift Del (DEL) | VAF 29/164 reads (18%) | catalogued as rs1220669390; called by mutect2, pindel, varscan2
- KMT2C | c.12774G>T p.K4258N | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51483491; called by muse, mutect2, varscan2
- KNL1 | c.3838G>A p.E1280K (on ENST00000346991 / NM_170589.5; = p.E1254K on NM_144508.5) | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); catalogued as COSV100705953; called by muse, mutect2, varscan2
- KRT17 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100245046; called by muse, mutect2, varscan2
- KRT7 | c.1025G>T p.R342L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100081330, COSV59332148; called by muse, mutect2, varscan2
- LAMA2 | c.1298C>A p.A433D | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV70342669, COSV70344342; called by muse, mutect2, varscan2
- LAMA2 | c.6767T>A p.V2256E | Missense Mutation (SNP) | VAF 81/355 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.751); catalogued as COSV101370084; called by muse, mutect2, varscan2
- LCOR | c.1810A>C p.S604R | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.73); catalogued as COSV99616590; called by muse, mutect2, varscan2
- LDHB | c.425A>G p.D142G | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV63364603; called by muse, mutect2, varscan2
- LETM1 | c.2077G>C p.E693Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV100245224; called by muse, mutect2
- LETM1 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769768748, COSV100245227; called by muse, mutect2, varscan2
- LIG4 | c.1207G>T p.V403L | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV100799702; called by muse, mutect2, varscan2
- LILRB2 | c.887G>T p.C296F | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV100079017, COSV58746491; called by muse, varscan2
- LMX1A | c.353G>T p.S118I | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.609); catalogued as COSV99671658; called by muse, mutect2, varscan2
- LRFN5 | c.1055C>G p.T352R | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs766205250, COSV99982564; called by muse, mutect2, varscan2
- LRP2 | c.12659G>T p.R4220L | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99786595; called by muse, mutect2, varscan2
- LRP6 | c.2252G>A p.R751K | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV99742404; called by muse, mutect2, varscan2
- LRP6 | c.1514A>G p.Y505C | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764096289, COSV99742407; called by muse, mutect2, varscan2
- LRRC7 | c.422-1G>T p.X141_splice (on ENST00000651989 / NM_001370785.2; = p.X108_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 11/59 reads (19%) | catalogued as COSV99224582; called by muse, mutect2, varscan2
- LYST | c.5631G>C p.L1877F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV101088244; called by muse, mutect2
- MACROH2A1 | c.907G>A p.D303N (on ENST00000510038; = p.D302N on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs766369780, COSV100427533; called by muse, mutect2, varscan2
- MAGEC1 | c.2050G>T p.E684* | Nonsense Mutation (SNP) | VAF 80/169 reads (47%) | catalogued as COSV99594867; called by muse, mutect2, varscan2
- MAGED1 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as rs782164446, COSV100431395; called by muse, mutect2, varscan2
- MAN2B1 | c.2696C>T p.S899L | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV55472319; called by muse, mutect2, varscan2
- MARVELD3 | c.594A>G p.R198= | Splice Region (SNP) | VAF 58/154 reads (38%) | catalogued as COSV99194793; called by muse, mutect2, varscan2
- MAS1L | c.262T>A p.C88S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.691); catalogued as COSV101009646; called by muse, mutect2, varscan2
- MCTP1 | c.827G>C p.R276P | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100386345, COSV56504684; called by muse, mutect2, varscan2
- MED13 | c.2188G>A p.D730N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV101180770, COSV67264518; called by muse, mutect2, varscan2
- MED13 | c.1529A>G p.N510S | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV101180771; called by muse, mutect2, varscan2
- MGAT5B | c.180A>T p.E60D | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100047285; called by muse, mutect2, varscan2
- MKX | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV101008539, COSV65393324; called by muse, mutect2, varscan2
- MPDZ | c.3271G>T p.A1091S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV100056176; called by muse, mutect2, varscan2
- MSANTD3 | c.182G>T p.S61I | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.861); catalogued as COSV100614407; called by muse, mutect2, varscan2
- MSH2 | c.607G>T p.G203* | Nonsense Mutation (SNP) | VAF 37/200 reads (19%) | catalogued as COSV99253242; called by muse, mutect2, varscan2
- MTG1 | c.363G>T p.Q121H | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV100448706; called by muse, mutect2, varscan2
- MTR | c.2489C>T p.S830L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100855243; called by muse, mutect2
- MTR | c.3520G>T p.A1174S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100855244; called by muse, mutect2
- MUC16 | c.39552G>C p.M13184I | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.187); catalogued as COSV101109607; called by muse, varscan2
- MUC16 | c.16581C>A p.S5527R | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV101198188, COSV67452197; called by muse, mutect2, varscan2
- MUC17 | c.2362C>A p.P788T | Missense Mutation (SNP) | VAF 188/764 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV100071647, COSV60306306; called by muse, varscan2
- MYEF2 | c.746T>A p.L249Q | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99981207; called by muse, mutect2
- MYEOV | c.398C>A p.A133D | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as COSV100456573; called by muse, mutect2, varscan2
- MYH1 | c.3019C>T p.H1007Y | Missense Mutation (SNP) | VAF 69/274 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs761447230, COSV99874948; called by muse, mutect2, varscan2
- MYLK2 | c.637G>T p.G213C | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101044659; called by muse, mutect2, varscan2
- MYLK3 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV101189053; called by muse, mutect2, varscan2
- MYO3A | c.2804T>C p.M935T | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56345888, COSV99778421; called by muse, mutect2, varscan2
- MYO7B | c.3825C>A p.S1275R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV101267883; called by muse, mutect2
- N4BP1 | c.266G>A p.C89Y | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1288937772, COSV99284772; called by muse, mutect2, varscan2
- NACA2 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 12/130 reads (9%) | catalogued as COSV101478535; called by muse, mutect2
- NBAS | c.886-1G>T p.X296_splice | Splice Site (SNP) | VAF 20/78 reads (26%) | catalogued as COSV99867299; called by muse, mutect2, varscan2
- NFASC | c.2405A>C p.Q802P (on ENST00000339876 / NM_001378329.1; = p.Q798P on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100362835; called by muse, mutect2, varscan2
- NFKBIA | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.251); catalogued as rs1330674964, COSV99394915; called by muse, mutect2, varscan2
- NHS | c.1176A>G p.I392M | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as COSV101196405; called by muse, mutect2, varscan2
- NLRC3 | c.153T>A p.D51E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV100072453; called by muse, mutect2, varscan2
- NMNAT1 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.152); catalogued as COSV101020384; called by muse, mutect2, varscan2
- NOS2 | c.3190C>A p.L1064M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV58227949; called by muse, mutect2, varscan2
- NOX4 | c.689A>T p.N230I | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV99629611; called by muse, mutect2, varscan2
- NT5C2 | c.357G>C p.L119F | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100583317; called by muse, mutect2
- NTRK3 | c.1028G>T p.R343L | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs183806623, COSV100448367, COSV58112677, COSV58116202; called by muse, mutect2, varscan2
- NUDCD1 | c.400G>T p.G134* | Nonsense Mutation (SNP) | VAF 37/388 reads (10%) | catalogued as COSV99516710; called by muse, mutect2
- NWD1 | c.3092C>T p.T1031M | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.074); catalogued as rs770074174, COSV60337281; called by muse, mutect2, varscan2
- NXF3 | c.1525C>A p.L509I | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV101221871; called by muse, mutect2, varscan2
- OBSCN | c.12328C>G p.H4110D | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV99472953; called by muse, mutect2
- OBSL1 | c.3751C>T p.P1251S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.113); catalogued as COSV99216236; called by muse, mutect2
- OIT3 | c.545-2A>T p.X182_splice | Splice Site (SNP) | VAF 25/184 reads (14%) | catalogued as COSV100467663; called by muse, mutect2, varscan2
- OR10G3 | c.560G>C p.R187T | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100336062; called by muse, mutect2, varscan2
- OR10R2 | c.517T>A p.F173I | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.344); catalogued as COSV100936762; called by muse, mutect2, varscan2
- OR13H1 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.428); catalogued as COSV100088118; called by muse, mutect2, varscan2
- OR1C1 | c.628C>G p.P210A | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV101376181; called by muse, varscan2
- OR1C1 | c.73C>G p.H25D | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV101376182; called by muse, mutect2
- OR2L8 | c.444G>T p.W148C | Missense Mutation (SNP) | VAF 104/410 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100594030, COSV61727789; called by muse, mutect2, varscan2
- OR4K14 | c.765C>A p.C255* | Nonsense Mutation (SNP) | VAF 9/76 reads (12%) | catalogued as rs746189195, COSV100520339; called by muse, mutect2, varscan2
- OR4K2 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 73/313 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV100064078; called by muse, mutect2, varscan2
- OR4S2 | c.693G>C p.R231S | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100412552; called by muse, mutect2
- OR56A3 | c.774C>G p.I258M | Missense Mutation (SNP) | VAF 80/298 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV100290048; called by muse, varscan2
- OR5AN1 | c.226A>T p.S76C | Missense Mutation (SNP) | VAF 48/307 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100004296; called by muse, mutect2, varscan2
- OR5AN1 | c.622G>T p.G208W | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100004297; called by muse, mutect2, varscan2
- OR5L1 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 22/462 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100449920; called by muse, mutect2
- OR8B12 | c.54C>A p.H18Q | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.02); catalogued as rs1449054257, COSV100172644, COSV60911100; called by muse, mutect2, varscan2
- OR8B3 | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.404); catalogued as rs1425380718, COSV100660358; called by muse, mutect2, varscan2
- OR8G1 | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.385); catalogued as COSV100422230; called by muse, mutect2, varscan2
- OR9G4 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV100265004; called by muse, mutect2, varscan2
- OTUD7A | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV100191909; called by muse, mutect2, varscan2
- P2RX2 | c.561T>G p.F187L (on ENST00000343948 / NM_170683.4; = p.F115L on NM_012226.5) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.798); catalogued as COSV100265408; called by muse, mutect2
- PABPC3 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs746078288, COSV55797266; called by muse, varscan2
- PARVG | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV100796027; called by muse, mutect2, varscan2
- PAX4 | c.145G>T p.V49L | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761898311, COSV100489962; called by muse, mutect2, varscan2
- PCDH10 | c.113C>G p.A38G | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV99993008; called by muse, mutect2, varscan2
- PCDH11X | c.3478C>T p.H1160Y | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as COSV100008402, COSV53462076; called by muse, mutect2
- PCDH11X | c.3850C>A p.Q1284K | Missense Mutation (SNP) | VAF 106/278 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV100008405; called by muse, mutect2, varscan2
- PCDH11Y | c.2420C>A p.S807* (on ENST00000400457 / NM_032973.2; = p.S796* on NM_032971.3) | Nonsense Mutation (SNP) | VAF 64/160 reads (40%) | catalogued as COSV99290599; called by muse, mutect2, varscan2
- PCDH11Y | c.3479A>T p.Q1160L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV99290603; called by muse, mutect2, varscan2
- PCDH15 | c.5746C>A p.Q1916K | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV57377979; called by muse, mutect2, varscan2
- PCDH8 | c.3014A>T p.Q1005L | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100131229; called by muse, mutect2, varscan2
- PCLO | c.11510G>A p.S3837N | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV100427560; called by muse, mutect2, varscan2
- PCLO | c.8695G>C p.D2899H | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100427561; called by muse, mutect2, varscan2
- PDK1 | c.1252G>T p.D418Y | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV99961118; called by muse, mutect2, varscan2
- PEG3 | c.3883G>T p.A1295S | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV99687384; called by muse, mutect2, varscan2
- PFKFB3 | c.1378A>T p.N460Y | Missense Mutation (SNP) | VAF 67/212 reads (32%) | PolyPhen possibly damaging (0.477); catalogued as COSV100431748; called by muse, mutect2, varscan2
- PFKL | c.910A>T p.T304S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100826985; called by muse, mutect2, varscan2
- PKHD1 | c.9325C>A p.H3109N | Missense Mutation (SNP) | VAF 102/354 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as COSV100581157; called by muse, mutect2, varscan2
- PLD1 | c.1769A>G p.Y590C | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1047396802, COSV100577647; called by muse, mutect2, varscan2
- PLEKHG4B | c.878T>A p.V293E (on ENST00000283426; = p.V649E on NM_052909.5) | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV99359818; called by muse, mutect2, varscan2
- POLR2B | c.2666A>T p.K889M | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58899070; called by muse, mutect2, varscan2
- POLR2I | c.137A>C p.Q46P | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV99387438; called by muse, mutect2, varscan2
- POU2F1 | c.332G>T p.G111V (on ENST00000541643 / NM_001365848.1; = p.G134V on NM_002697.4) | Missense Mutation (SNP) | VAF 126/371 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99610465; called by muse, mutect2, varscan2
- PPEF2 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | catalogued as COSV99714126; called by muse, mutect2, varscan2
- PPP3CA | c.253G>T p.V85F | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV100547335; called by muse, mutect2, varscan2
- PRAMEF10 | c.1314G>T p.M438I | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV99338754; called by muse, mutect2, varscan2
- PRDM13 | c.568C>A p.L190I | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV65030523; called by muse, mutect2, varscan2
- PRDX3 | c.460G>C p.G154R | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100045297; called by muse, mutect2, varscan2
- PRF1 | c.1383G>C p.W461C | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100942526; called by muse, mutect2, varscan2
- PRKDC | c.2746G>C p.E916Q | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100038500; called by muse, mutect2, varscan2
- PRR27 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV100748756; called by muse, mutect2, varscan2
- PRUNE2 | c.6874C>A p.L2292M | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as COSV100944233; called by muse, mutect2, varscan2
- PTER | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100126553, COSV54347381; called by muse, mutect2, varscan2
- PTPRM | c.287G>C p.C96S | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1182623949, COSV100154998; called by muse, mutect2, varscan2
- PUS10 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV100369392; called by muse, mutect2, varscan2
- PYGO1 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.03); catalogued as rs762180451; called by mutect2, varscan2
- RACGAP1 | c.824T>A p.V275E | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100407534; called by muse, mutect2, varscan2
- RAD51C | c.405-2A>G p.X135_splice | Splice Site (SNP) | VAF 19/167 reads (11%) | catalogued as COSV99541456; called by muse, mutect2, varscan2
- RASGEF1A | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100988635; called by muse, mutect2
- RBM26 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV99935823; called by muse, mutect2, varscan2
- RBM47 | c.1174G>T p.G392W | Missense Mutation (SNP) | VAF 79/285 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99920132; called by muse, mutect2, varscan2
- REG3G | c.271C>A p.L91M | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.486); catalogued as COSV55449195; called by muse, mutect2, varscan2
- RFTN2 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as COSV54389196; called by muse, mutect2, varscan2
- RGL3 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs750883806, COSV100992804, COSV66512198; called by muse, mutect2
- RGS19 | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as COSV100180598; called by muse, mutect2, varscan2
- RGS7 | c.990G>T p.W330C | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100464791; called by muse, mutect2
- RHBDL1 | c.605C>T p.S202L (on ENST00000219551 / NM_001318733.2; = p.S137L on NM_001278720.2) | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs758326393, COSV99555395; called by muse, mutect2, varscan2
- RHOXF1 | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as COSV54294858; called by muse, mutect2, varscan2
- RLF | c.3868A>G p.S1290G | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV101035093; called by muse, mutect2, varscan2
- RP1L1 | c.2880G>T p.W960C | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756532285, COSV101222961; called by muse, mutect2, varscan2
- RPGRIP1 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as COSV99250475; called by muse, mutect2, varscan2
- RRP8 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as COSV99601806; called by muse, mutect2, varscan2
- RSPH6A | c.420G>T p.E140D | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99679572; called by muse, mutect2, varscan2
- RUNX1 | c.10G>C p.D4H | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100296850; called by muse, mutect2, varscan2
- RYR2 | c.8255A>T p.K2752M | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100768078; called by muse, mutect2
- RYR2 | c.12328C>G p.P4110A | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100767215; called by muse, mutect2, varscan2
- SCEL | c.1337G>T p.G446V (on ENST00000349847 / NM_144777.3; = p.G426V on NM_003843.4) | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV100582603; called by muse, mutect2, varscan2
- SCN3A | c.4550G>T p.G1517V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99325710, COSV99326900; called by muse, mutect2, varscan2
- SEC16B | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1484832506, COSV100381255, COSV100381860; called by muse, mutect2, varscan2
- SEL1L | c.476A>T p.Y159F | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.777); catalogued as COSV100377659; called by muse, mutect2, varscan2
- SHOX | c.454C>G p.Q152E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as CM074509, COSV100478768; called by muse, mutect2
- SIPA1L2 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 28/282 reads (10%) | catalogued as COSV99477200; called by muse, mutect2, varscan2
- SLC13A3 | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99286192; called by muse, mutect2
- SLC17A6 | c.748+2T>C p.X250_splice | Splice Site (SNP) | VAF 21/67 reads (31%) | catalogued as COSV99580783; called by muse, mutect2, varscan2
- SLC18A3 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100339772; called by muse, mutect2, varscan2
- SLC22A9 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs143461929, COSV54169664; called by muse, mutect2, varscan2
- SLC27A5 | c.899-1G>T p.X300_splice | Splice Site (SNP) | VAF 12/66 reads (18%) | catalogued as COSV99564162; called by muse, mutect2, varscan2
- SLC39A12 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.482); catalogued as COSV101069841; called by muse, mutect2
- SLC52A3 | c.551A>G p.E184G | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs113864305, COSV99447598; called by muse, mutect2, varscan2
- SLC5A12 | c.130G>T p.G44W | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99744219; called by muse, mutect2, varscan2
- SLC6A12 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62885681; called by muse, mutect2, varscan2
- SLC7A4 | c.1122C>A p.F374L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV100298528, COSV60384263; called by muse, mutect2, varscan2
- SLC9A3 | c.1647+2T>C p.X549_splice | Splice Site (SNP) | VAF 42/114 reads (37%) | catalogued as COSV99375679; called by muse, mutect2, varscan2
- SLC9A4 | c.435C>A p.F145L | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV99762717; called by muse, mutect2
- SMAD2 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV100053360; called by muse, mutect2, varscan2
- SMAD9 | c.349T>G p.F117V | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100614430; called by muse, mutect2
- SMARCA4 | c.2439-2A>T p.X813_splice | Splice Site (SNP) | VAF 40/125 reads (32%) | catalogued as COSV60797118; called by muse, varscan2
- SMS | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV101047918; called by muse, mutect2, varscan2
- SMURF2 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99300343; called by muse, mutect2
- SNX1 | c.1037A>T p.Q346L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99975919; called by muse, mutect2
- SNX2 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV101075503; called by muse, mutect2
- SOGA3 | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV100846781; called by muse, mutect2, varscan2
- SORCS1 | c.3267C>A p.A1089= | Splice Region (SNP) | VAF 6/64 reads (9%) | catalogued as COSV53857380, COSV99543460; called by muse, mutect2
- SPATA5L1 | c.1994G>A p.C665Y | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.053); catalogued as COSV99972829; called by muse, mutect2, varscan2
- SPATA6 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1185535069, COSV100893721; called by muse, mutect2, varscan2
- SPTA1 | c.6730C>A p.Q2244K | Missense Mutation (SNP) | VAF 109/367 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934287; called by muse, mutect2, varscan2
- SPTA1 | c.5995C>G p.Q1999E | Missense Mutation (SNP) | VAF 84/794 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV100934289; called by muse, mutect2, varscan2
- ST8SIA2 | c.1102G>C p.V368L | Missense Mutation (SNP) | VAF 9/144 reads (6%) | PolyPhen benign (0.229); catalogued as COSV99184367; called by muse, mutect2
- STOX1 | c.2412del p.L805Cfs*20 | Frame Shift Del (DEL) | VAF 21/133 reads (16%) | catalogued as COSV53813837; called by mutect2, pindel, varscan2
- SYCP2L | c.132A>T p.K44N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV99304679; called by muse, mutect2, varscan2
- SYDE1 | c.1234C>A p.Q412K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99654580; called by muse, mutect2, varscan2
- SYNE1 | c.14620G>A p.E4874K (on ENST00000367255 / NM_182961.4; = p.E4803K on NM_033071.3) | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as rs147947110; called by muse, mutect2, varscan2
- SYNE2 | c.7160A>T p.Q2387L | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100646717; called by muse, mutect2, varscan2
- SYNE2 | c.8596A>T p.T2866S | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV100646718; called by muse, mutect2, varscan2
- SYNJ1 | c.3043A>T p.N1015Y | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV100448951; called by muse, mutect2, varscan2
- SYT15 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV100970193; called by muse, mutect2, varscan2
- SYT2 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as COSV100937119; called by muse, mutect2, varscan2
- TAAR9 | c.65G>A p.C22Y | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV101453297; called by muse, mutect2, varscan2
- TAS2R5 | c.522T>A p.N174K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV99924757; called by muse, mutect2, varscan2
- TASOR2 | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100049984; called by muse, mutect2
- TBC1D4 | c.1390C>A p.L464I | Missense Mutation (SNP) | VAF 35/420 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100884531; called by muse, mutect2
- TBC1D5 | c.1075G>C p.G359R | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as COSV99509331; called by muse, mutect2, varscan2
- TCHH | c.3302G>C p.R1101T | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV100914902; called by muse, mutect2, varscan2
- TECPR2 | c.3302A>T p.K1101M | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV100849825; called by muse, mutect2, varscan2
- TEX15 | c.523G>T p.E175* (on ENST00000256246; = p.E558* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 20/93 reads (22%) | catalogued as COSV99820725; called by muse, mutect2, varscan2
- TEX9 | c.92A>T p.D31V | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100771300; called by muse, mutect2, varscan2
- TGFB2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/75 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100859887; called by muse, mutect2, varscan2
- THADA | c.4250A>G p.Y1417C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100367963; called by muse, mutect2
- THSD7B | c.4687G>C p.V1563L (on ENST00000272643; = p.V1561L on NM_001316349.2) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.275); catalogued as rs372041308, COSV99744669; called by muse, mutect2
- TLR4 | c.996G>T p.W332C (on ENST00000355622 / NM_138554.5; = p.W292C on NM_003266.4) | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100842662, COSV62923853; called by muse, mutect2, varscan2
- TMEM248 | c.883A>G p.S295G | Missense Mutation (SNP) | VAF 69/260 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1184808259, COSV100447229; called by muse, mutect2, varscan2
- TMEM266 | c.714G>C p.K238N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV101189563; called by muse, mutect2, varscan2
- TMEM39B | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.082); catalogued as rs138878956; called by muse, mutect2
- TMEM87B | c.579C>G p.S193R | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV99314044; called by muse, mutect2, varscan2
- TMPRSS15 | c.938C>G p.A313G | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV99516916; called by muse, mutect2, varscan2
- TMPRSS6 | c.1264A>T p.T422S | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV100695403; called by muse, mutect2, varscan2
- TNFRSF8 | c.87T>G p.C29W | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99821100; called by muse, mutect2, varscan2
- TNN | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99078382, COSV99511127; called by muse, mutect2
- TNXB | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as rs767342071, COSV64489713; called by muse, mutect2, varscan2
- TOP3B | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs546455586, COSV100592325; called by muse, mutect2, varscan2
- TP53 | c.461del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 21/86 reads (24%) | catalogued as CM951223, COSV52667239, COSV52783646, COSV53625267; called by mutect2, pindel, varscan2
- TRAK2 | c.2269A>T p.S757C | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.911); catalogued as COSV100216634; called by muse, mutect2, varscan2
- TRIM23 | c.538C>G p.Q180E | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs373852058; called by muse, mutect2
- TRIM33 | c.2705G>C p.C902S | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100635046; called by muse, mutect2
- TRPA1 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as COSV100083211; called by muse, mutect2, varscan2
- TRPM1 | c.3548G>T p.R1183L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV56642390; called by muse, mutect2, varscan2
- TRPM7 | c.1615A>T p.S539C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV100539401; called by muse, mutect2, varscan2
- TSPYL5 | c.1241G>T p.S414I | Missense Mutation (SNP) | VAF 175/411 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as COSV100438894; called by muse, mutect2, varscan2
- TTC14 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1304311939, COSV99931812; called by muse, mutect2, varscan2
- TTN | c.93281T>C p.I31094T (on ENST00000591111; = p.I23670T on NM_003319.4) | Missense Mutation (SNP) | VAF 27/107 reads (25%) | PolyPhen benign (0.005); catalogued as COSV60293100; called by muse, mutect2, varscan2
- TTN | c.50026A>T p.T16676S (on ENST00000591111; = p.T9252S on NM_003319.4) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | PolyPhen benign (0.001); catalogued as COSV100594914; called by muse, mutect2, varscan2
- TTN | c.47437G>T p.G15813C (on ENST00000591111; = p.G8389C on NM_003319.4) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | PolyPhen probably damaging (1); catalogued as COSV100594915; called by muse, mutect2, varscan2
- TTN | c.39011A>G p.K13004R (on ENST00000591111; = p.K5580R on NM_003319.4) | Missense Mutation (SNP) | VAF 24/81 reads (30%) | PolyPhen benign (0.274); catalogued as COSV100594918; called by muse, mutect2, varscan2
- TTN | c.26048C>T p.A8683V (on ENST00000591111; = p.A7756V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | PolyPhen benign (0.168); catalogued as rs752994608, COSV100594919; called by muse, mutect2, varscan2
- TUBA3C | c.1193T>G p.M398R | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV101313834; called by muse, mutect2, varscan2
- TXLNB | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV100624839; called by muse, mutect2, varscan2
- UBR5 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 25/303 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99639433; called by muse, mutect2
- UCP1 | c.558C>G p.I186M | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV99530106; called by muse, mutect2, varscan2
- UFL1 | c.1614G>T p.K538N | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.84); catalogued as COSV100990010; called by muse, mutect2, varscan2
- UMOD | c.1024G>C p.V342L | Missense Mutation (SNP) | VAF 16/185 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV100208006; called by muse, mutect2
- UNC13A | c.715T>C p.Y239H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV99407151; called by muse, mutect2, varscan2
- USH2A | c.14165C>A p.P4722H | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as rs867233074, COSV100229233; called by muse, mutect2, varscan2
- USP26 | c.2084A>G p.N695S | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.734); catalogued as COSV100896548; called by muse, mutect2, varscan2
- USP29 | c.2066C>A p.P689Q | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.977); catalogued as COSV99517650; called by muse, mutect2, varscan2
- USP34 | c.2267A>G p.H756R | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.84); catalogued as rs745381929; called by muse, mutect2, varscan2
- USP46 | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as COSV101484206; called by muse, mutect2, varscan2
- VCAM1 | c.233C>A p.S78Y | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99658206, COSV99658821; called by muse, mutect2, varscan2
- VNN1 | c.1259C>A p.T420N | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100907686; called by muse, mutect2, varscan2
- VPS13C | c.8134G>T p.E2712* (on ENST00000644861 / NM_020821.3; = p.E2669* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 20/97 reads (21%) | catalogued as COSV99827252; called by muse, mutect2, varscan2
- VPS28 | c.609G>T p.Q203H | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52872569, COSV99465408; called by muse, mutect2, varscan2
- VPS35L | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV99219700; called by muse, mutect2, varscan2
- VRK1 | c.296G>T p.W99L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99388217; called by muse, mutect2, varscan2
- WDFY3 | c.7221G>T p.A2407= | Splice Region (SNP) | VAF 85/347 reads (24%) | catalogued as COSV55705851, COSV99882089; called by muse, mutect2, varscan2
- WDR17 | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as COSV99706811; called by muse, mutect2
- WDR36 | c.2176G>C p.E726Q | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV101550949; called by muse, mutect2, varscan2
- WDR88 | c.412C>A p.R138S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV100866412, COSV63452513; called by mutect2, varscan2
- XKR4 | c.1119C>G p.I373M | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.603); catalogued as COSV100530922; called by muse, mutect2, varscan2
- ZAN | c.2258C>T p.T753I | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV100769188; called by muse, varscan2
- ZEB1 | c.2380C>G p.P794A | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV100313658, COSV58037936; called by muse, mutect2
- ZEB1 | c.2987C>T p.T996I | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV100313659; called by muse, mutect2
- ZFHX4 | c.727A>G p.S243G | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.121); catalogued as COSV99256492; called by muse, mutect2, varscan2
- ZFP14 | c.952G>T p.G318W | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV99524984; called by muse, mutect2, varscan2
- ZKSCAN1 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV100164098; called by muse, mutect2, varscan2
- ZNF107 | c.1384C>G p.H462D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100788223, COSV61328705; called by muse, mutect2, varscan2
- ZNF107 | c.1571A>T p.N524I | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100788224; called by muse, mutect2, varscan2
- ZNF251 | c.818C>G p.T273S | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.043); catalogued as rs367867958; called by muse, mutect2, varscan2
- ZNF253 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100849456; called by muse, mutect2, varscan2
- ZNF304 | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 27/151 reads (18%) | catalogued as COSV99988411; called by muse, mutect2, varscan2
- ZNF337 | c.2140G>T p.E714* | Nonsense Mutation (SNP) | VAF 31/284 reads (11%) | catalogued as COSV99430001; called by muse, mutect2, varscan2
- ZNF485 | c.1095G>C p.K365N | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.115); catalogued as COSV100700160; called by muse, mutect2, varscan2
- ZNF667 | c.446G>T p.C149F | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99410047; called by muse, mutect2, varscan2
- ZNF705A | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774745625, COSV63733083; called by muse, mutect2, varscan2
- ZNF714 | c.1391G>T p.R464L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.058); catalogued as rs370427342, COSV52511437; called by muse, mutect2, varscan2
- ZNF804B | c.1418A>C p.Y473S | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60845648; called by muse, mutect2, varscan2
- ZNF831 | c.4212G>T p.E1404D | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as COSV100925766; called by muse, mutect2, varscan2
- ZPBP | c.650A>G p.H217R | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM118240, COSV99249076; called by muse, mutect2, varscan2
- ZSCAN18 | c.20C>G p.A7G | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV99559091; called by muse, mutect2, varscan2
- C12orf66 | c.63_88del p.F21Lfs*5 | Frame Shift Del (DEL) | VAF 6/65 reads (9%) | called by mutect2, pindel
- CDH10 | c.1761_1762del p.A588Lfs*2 | Frame Shift Del (DEL) | VAF 30/178 reads (17%) | called by pindel, varscan2
- COL22A1 | c.4274_4276delinsAA p.T1425Kfs*3 | Frame Shift Del (DEL) | VAF 14/135 reads (10%) | called by pindel, varscan2*
- GLI2 | c.1737del p.K580Rfs*98 (on ENST00000361492 / NM_001374353.1; = p.K597Rfs*98 on NM_005270.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 37/175 reads (21%) | called by mutect2, pindel, varscan2
- GPR61 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.01); called by muse, mutect2
- GUCY2F | c.3009dup p.G1004Wfs*34 | Frame Shift Ins (INS) | VAF 30/94 reads (32%) | called by mutect2, pindel, varscan2
- IGHV1OR15-9 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, varscan2
- IGHV1OR21-1 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 76/790 reads (10%) | called by muse, mutect2
- IGKV1D-13 | c.223A>C p.S75R | Missense Mutation (SNP) | VAF 56/324 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IGKV3-11 | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ITGB2 | c.20del p.P7Hfs*43 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- KNDC1 | c.3963C>G p.C1321W | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.961); called by muse, mutect2
- KRT83 | c.646_647del p.L216Kfs*26 | Frame Shift Del (DEL) | VAF 97/354 reads (27%) | called by pindel, varscan2
- LRP2 | c.2487del p.S830Rfs*3 | Frame Shift Del (DEL) | VAF 46/201 reads (23%) | called by mutect2, pindel, varscan2
- LRRN2 | c.1789del p.L597Cfs*29 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | called by mutect2, pindel, varscan2
- MAGEB10 | c.55_56insT p.R19Lfs*37 | Frame Shift Ins (INS) | VAF 24/58 reads (41%) | called by mutect2, pindel*, varscan2
- MUC5B | c.6740_6752del p.H2247Pfs*56 | Frame Shift Del (DEL) | VAF 23/131 reads (18%) | called by mutect2, varscan2
- NEK5 | c.411_412delinsG p.S137Rfs*14 | Frame Shift Del (DEL) | VAF 25/119 reads (21%) | called by pindel, varscan2*
- NR4A2 | c.1707_1708insT p.L570Sfs*20 | Frame Shift Ins (INS) | VAF 29/130 reads (22%) | called by mutect2, pindel*, varscan2
- OR8G5 | c.284del p.P95Lfs*4 | Frame Shift Del (DEL) | VAF 40/208 reads (19%) | called by mutect2, pindel, varscan2
- RIPK2 | c.1179_1187delinsGA p.S393Rfs*24 | Frame Shift Del (DEL) | VAF 58/261 reads (22%) | called by pindel, varscan2*
- TCN1 | c.106del p.L36* | Frame Shift Del (DEL) | VAF 39/233 reads (17%) | called by mutect2, pindel, varscan2
- TMEM144 | c.27_32del p.F10_G11del | In Frame Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- USP17L2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.307); called by muse, mutect2
- WDFY1 | c.954del p.Q319Rfs*41 | Frame Shift Del (DEL) | VAF 75/359 reads (21%) | called by mutect2, pindel, varscan2
- XIRP2 | c.6365del p.P2122Hfs*20 (on ENST00000628543; = p.P2297Hfs*20 on NM_152381.6) | Frame Shift Del (DEL) | VAF 55/192 reads (29%) | called by mutect2, pindel, varscan2
- ZNF658 | c.752A>G p.N251S | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF708 | c.1128dup p.S377Lfs*5 | Frame Shift Ins (INS) | VAF 27/92 reads (29%) | called by mutect2, pindel, varscan2
- ABCA1 | c.4788C>T p.N1596= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as COSV101036560; called by muse, mutect2, varscan2
- ABCA1 | c.855G>C p.V285= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV101036561; called by muse, mutect2, varscan2
- ABCA3 | c.1983G>C p.R661= | Silent (SNP) | VAF 19/182 reads (10%) | catalogued as COSV100068033; called by muse, mutect2, varscan2
- ADAMTS12 | c.3678C>G p.P1226= | Silent (SNP) | VAF 40/272 reads (15%) | catalogued as COSV100710033, COSV100710297; called by muse, mutect2, varscan2
- ADGRV1 | c.12837A>C p.S4279= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV101315516; called by muse, varscan2
- ALDH16A1 | c.1059C>G p.V353= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99512609; called by muse, mutect2, varscan2
- ASIC2 | c.549C>T p.F183= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV100725759; called by muse, mutect2
- ATP8B4 | c.1755C>A p.L585= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV99463786; called by muse, mutect2, varscan2
- BAZ1A | c.3447G>T p.A1149= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as COSV100701088, COSV100701208; called by muse, mutect2, varscan2
- BDKRB2 | c.780G>A p.K260= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100020826, COSV100020866; called by muse, mutect2, varscan2
- BRCC3 | c.33G>C p.A11= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100341448; called by muse, mutect2
- CARD8 | c.744C>T p.I248= (on ENST00000651546 / NM_001184900.3; = p.I198= on NM_014959.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 30/148 reads (20%) | catalogued as COSV100750998; called by muse, mutect2, varscan2
- CDH8 | c.1185T>A p.T395= | Silent (SNP) | VAF 41/180 reads (23%) | catalogued as COSV100179682; called by muse, mutect2, varscan2
- CDH8 | c.708C>A p.A236= | Silent (SNP) | VAF 40/133 reads (30%) | catalogued as COSV100179684; called by muse, mutect2, varscan2
- CFHR5 | c.579G>A p.G193= | Silent (SNP) | VAF 15/184 reads (8%) | catalogued as COSV56820870; called by muse, mutect2
- CHD9 | c.3588C>T p.A1196= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs773701804, COSV99528718; called by muse, mutect2, varscan2
- CHST13 | c.939C>T p.P313= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1414764165, COSV100080960; called by muse, mutect2, varscan2
- CLCA4 | c.2037G>T p.R679= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV99760230; called by muse, mutect2, varscan2
- CLDN18 | c.243C>A p.A81= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV99480614; called by muse, mutect2, varscan2
- CLSTN2 | c.819C>T p.G273= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV101515540, COSV71718528; called by muse, mutect2
- COL11A1 | c.396G>T p.G132= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV100615219; called by muse, mutect2, varscan2
- CPNE2 | c.261G>A p.E87= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV99321231; called by muse, mutect2, varscan2
- CSMD1 | c.4227G>A p.E1409= (on ENST00000520002; = p.E1408= on NM_033225.6) | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs766412564, COSV100144085; called by muse, mutect2, varscan2
- DIDO1 | c.1506G>T p.T502= | Silent (SNP) | VAF 52/252 reads (21%) | catalogued as COSV99824763; called by muse, mutect2, varscan2
- DYSF | c.1431C>T p.T477= | Silent (SNP) | VAF 24/142 reads (17%) | catalogued as COSV99244452; called by muse, mutect2, varscan2
- EHMT1 | c.2028G>T p.G676= | Silent (SNP) | VAF 82/299 reads (27%) | catalogued as COSV100603501; called by muse, mutect2, varscan2
- EIF3F | c.12G>T p.P4= | Silent (SNP) | VAF 69/226 reads (31%) | catalogued as COSV100562486; called by muse, mutect2, varscan2
- ERICH3 | c.3030G>A p.E1010= | Silent (SNP) | VAF 50/225 reads (22%) | catalogued as COSV100443441; called by muse, mutect2, varscan2
- FAM135B | c.1254G>A p.A418= | Silent (SNP) | VAF 36/207 reads (17%) | catalogued as rs746092198, COSV99419116; called by muse, mutect2, varscan2
- FBLN7 | c.894C>T p.S298= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as COSV55615498; called by muse, mutect2, varscan2
- FGF21 | c.330G>C p.L110= | Silent (SNP) | VAF 9/187 reads (5%) | catalogued as COSV99711370; called by muse, mutect2
- FOXG1 | c.1236C>A p.G412= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV100486557; called by muse, mutect2, varscan2
- FZD4 | c.1272G>C p.G424= | Silent (SNP) | VAF 27/235 reads (11%) | catalogued as COSV101536022; called by muse, mutect2, varscan2
- GABRB3 | c.945C>A p.V315= | Silent (SNP) | VAF 23/132 reads (17%) | catalogued as COSV100158286; called by muse, mutect2, varscan2
- GAPDHS | c.42C>G p.V14= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV99722650; called by muse, mutect2, varscan2
- GHSR | c.396C>A p.L132= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV99576693; called by muse, mutect2, varscan2
- GPR119 | c.498G>A p.V166= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV99358533; called by muse, mutect2, varscan2
- HCRTR2 | c.675C>T p.I225= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100904170; called by muse, mutect2, varscan2
- HEXA | c.192C>T p.A64= | Silent (SNP) | VAF 34/310 reads (11%) | catalogued as COSV99173677; called by muse, mutect2, varscan2
- HGS | c.714G>C p.L238= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV100230226; called by muse, mutect2, varscan2
- HMOX1 | c.777C>G p.L259= | Silent (SNP) | VAF 31/327 reads (9%) | catalogued as COSV99330589; called by muse, mutect2
- HRNR | c.5148C>T p.G1716= | Silent (SNP) | VAF 51/417 reads (12%) | called by muse, mutect2, varscan2
- HTR3C | c.384G>T p.V128= | Silent (SNP) | VAF 52/144 reads (36%) | catalogued as COSV100570499; called by muse, mutect2, varscan2
- IFIH1 | c.987C>A p.L329= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as rs746614543, COSV99718404; called by muse, mutect2, varscan2
- INHBA | c.651C>A p.T217= | Silent (SNP) | VAF 4/80 reads (5%) | catalogued as COSV99637156; called by muse, mutect2
- KCNA10 | c.336G>T p.L112= | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as COSV100871394; called by muse, mutect2
- KCNH8 | c.1779G>C p.S593= | Silent (SNP) | VAF 35/151 reads (23%) | catalogued as COSV100108432, COSV100108559; called by muse, mutect2, varscan2
- KCNN3 | c.2151G>C p.V717= (on ENST00000618040 / NM_001204087.1; = p.V702= on NM_002249.6) | Silent (SNP) | VAF 22/200 reads (11%) | catalogued as COSV99677405; called by muse, mutect2, varscan2
- KCNN3 | c.1371C>T p.I457= | Silent (SNP) | VAF 19/166 reads (11%) | catalogued as COSV99677410; called by muse, mutect2, varscan2
- KIF26B | c.4773G>A p.R1591= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100831641; called by muse, mutect2, varscan2
- KLHL17 | c.1050G>T p.G350= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100497847; called by muse, mutect2, varscan2
- KLK3 | c.129C>T p.A43= | Silent (SNP) | VAF 37/196 reads (19%) | catalogued as rs374094231, COSV100385902; called by muse, mutect2, varscan2
- KRT75 | c.1201C>A p.R401= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs200076348, COSV52871189; called by muse, mutect2, varscan2
- KSR2 | c.924G>T p.L308= | Silent (SNP) | VAF 23/199 reads (12%) | catalogued as COSV100347072, COSV100351467; called by muse, mutect2, varscan2
- LAMA4 | c.3298C>T p.L1100= (on ENST00000230538 / NM_001105206.3; = p.L1093= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/150 reads (15%) | catalogued as COSV100037644; called by muse, mutect2, varscan2
- LAS1L | c.1593A>C p.T531= | Silent (SNP) | VAF 51/121 reads (42%) | catalogued as COSV100408473; called by muse, mutect2, varscan2
- LRRC7 | c.4323G>T p.V1441= (on ENST00000651989 / NM_001370785.2; = p.V1361= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/101 reads (22%) | called by muse, varscan2
- MAGEA4 | c.522C>T p.S174= | Silent (SNP) | VAF 58/167 reads (35%) | catalogued as COSV99367296; called by muse, mutect2, varscan2
- MDH2 | c.705G>T p.T235= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100242565; called by muse, mutect2, varscan2
- MMP2 | c.210G>A p.L70= | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as COSV99527423; called by muse, mutect2, varscan2
- MRPL53 | c.338G>A p.*113= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV99251992; called by muse, mutect2
- MTIF3 | c.30A>G p.T10= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV101137428; called by muse, mutect2, varscan2
- MTMR3 | c.339A>G p.R113= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as COSV100070467; called by muse, mutect2, varscan2
- MUC16 | c.2850G>A p.Q950= | Silent (SNP) | VAF 33/206 reads (16%) | catalogued as COSV101198189; called by muse, mutect2, varscan2
- MUC5B | c.14544C>T p.L4848= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as COSV101500038; called by muse, mutect2
- MYBPC3 | c.2814C>A p.A938= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99919943; called by muse, mutect2, varscan2
- NAGK | c.366G>T p.V122= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99730463; called by muse, mutect2, varscan2
- NEO1 | c.2286G>A p.E762= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV56072879, COSV99981295; called by muse, mutect2, varscan2
- NES | c.4860G>A p.E1620= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as rs1369909757, COSV100957756; called by muse, mutect2, varscan2
- NOBOX | c.1137T>A p.P379= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99779197; called by muse, mutect2
- NOTCH2 | c.3693G>T p.R1231= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV99862815; called by muse, mutect2, varscan2
- NPHS1 | c.3546G>T p.T1182= | Silent (SNP) | VAF 35/228 reads (15%) | catalogued as COSV100799610; called by muse, mutect2, varscan2
- NXPH2 | c.168G>T p.L56= | Silent (SNP) | VAF 53/213 reads (25%) | catalogued as COSV99740160; called by muse, mutect2, varscan2
- OR10Z1 | c.882T>C p.N294= | Silent (SNP) | VAF 151/408 reads (37%) | catalogued as COSV100778941; called by muse, mutect2, varscan2
- OR4F15 | c.111G>A p.A37= | Silent (SNP) | VAF 41/320 reads (13%) | catalogued as rs745598454, COSV100173825; called by muse, mutect2, varscan2
- OR5K1 | c.550T>C p.L184= | Silent (SNP) | VAF 76/297 reads (26%) | catalogued as rs1202376484, COSV100220873; called by muse, mutect2, varscan2
- OR9Q2 | c.78T>C p.P26= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs1163105277, COSV100285323, COSV100285573; called by muse, mutect2, varscan2
- OSBPL6 | c.1848G>A p.S616= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs200622460, COSV99506584; called by muse, mutect2, varscan2
- OTOF | c.4122G>A p.K1374= (on ENST00000272371 / NM_194248.3; = p.K607= on NM_004802.4) | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV99716577, COSV99716841; called by muse, mutect2, varscan2
- PAPPA2 | c.1488C>A p.P496= | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as COSV100866547, COSV62786769; called by muse, mutect2, varscan2
- PCDH17 | c.1284C>T p.R428= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100931438; called by muse, mutect2, varscan2
- PCM1 | c.501A>T p.G167= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV100278813; called by muse, mutect2, varscan2
- PDE3A | c.825G>A p.L275= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as rs750288734, COSV62967221; called by muse, mutect2, varscan2
- PEG3 | c.1896T>C p.C632= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as COSV99687388, COSV99690425; called by muse, mutect2, varscan2
- PIEZO2 | c.7473A>G p.K2491= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as rs1158885112, COSV99554450; called by muse, mutect2, varscan2
- PITPNM1 | c.552G>T p.G184= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV100039323; called by muse, mutect2, varscan2
- PLBD2 | c.1188G>T p.R396= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV99785196; called by muse, mutect2
- PLEKHG7 | c.417T>A p.P139= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as rs780655140, COSV101188828; called by muse, mutect2, varscan2
- PTPRN2 | c.1851G>T p.A617= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs971336611, COSV101233684; called by muse, mutect2, varscan2
- RAPGEF2 | c.1626C>T p.I542= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100030551; called by muse, mutect2, varscan2
- RRP8 | c.783G>T p.G261= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs780329905, COSV99601805; called by mutect2, varscan2
- SFRP4 | c.549G>A p.V183= | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as COSV101460869; called by muse, mutect2, varscan2
- SIPA1L3 | c.1728C>T p.T576= | Silent (SNP) | VAF 35/182 reads (19%) | catalogued as rs368773539; called by muse, mutect2, varscan2
- SLC24A4 | c.636C>T p.I212= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs765944162, COSV100104274; called by muse, mutect2, varscan2
- SLC35B1 | c.201C>T p.I67= (on ENST00000649906; = p.I30= on NM_005827.4) | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs375347133; called by muse, mutect2
- SLC52A3 | c.768C>G p.L256= | Silent (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- SLIT1 | c.3544C>T p.L1182= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV99820638; called by muse, mutect2
- SON | c.2652G>A p.Q884= | Silent (SNP) | VAF 26/186 reads (14%) | catalogued as rs747420533, COSV99276892; called by muse, varscan2
- SPACA3 | c.69G>T p.V23= | Silent (SNP) | VAF 45/162 reads (28%) | catalogued as COSV99284106; called by muse, mutect2, varscan2
- SPIC | c.453C>A p.A151= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV100162846; called by muse, mutect2, varscan2
- SPTBN4 | c.471C>A p.V157= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV100150067; called by muse, mutect2, varscan2
- ST14 | c.825G>T p.L275= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99598483; called by mutect2, varscan2
- SYNE1 | c.8109T>C p.I2703= (on ENST00000367255 / NM_182961.4; = p.I2710= on NM_033071.3) | Silent (SNP) | VAF 39/141 reads (28%) | catalogued as COSV99553955; called by muse, mutect2, varscan2
- TBL2 | c.819C>T p.F273= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs782708722, COSV99979468; called by muse, mutect2, varscan2
- TCN2 | c.180C>T p.L60= | Silent (SNP) | VAF 47/309 reads (15%) | catalogued as rs919468097, COSV99308369; called by muse, mutect2, varscan2
- TIGAR | c.297G>T p.A99= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as COSV99463344; called by muse, mutect2, varscan2
- TMEM132D | c.1719G>A p.Q573= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV101242544; called by muse, mutect2, varscan2
- TNR | c.1047G>A p.P349= | Silent (SNP) | VAF 21/204 reads (10%) | catalogued as rs768539522, COSV54875635; called by muse, mutect2, varscan2
- TNRC6B | c.4794G>T p.L1598= (on ENST00000454349 / NM_001162501.2; = p.L1488= on NM_015088.3) | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV100109059; called by muse, mutect2, varscan2
- TPTE | c.906C>A p.I302= (on ENST00000618007 / NM_199261.4; = p.I284= on NM_199259.4) | Silent (SNP) | VAF 26/240 reads (11%) | called by muse, mutect2, varscan2
- TRPS1 | c.2700G>C p.L900= (on ENST00000220888 / NM_001330599.2; = p.L913= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/321 reads (8%) | catalogued as COSV99628518; called by muse, mutect2
- TUBB2B | c.534G>C p.T178= | Silent (SNP) | VAF 72/316 reads (23%) | catalogued as rs765021378, COSV52533284; called by muse, mutect2, varscan2
- UBR5 | c.3129G>T p.L1043= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as COSV99639429; called by muse, mutect2, varscan2
- WBP1L | c.156C>A p.I52= | Silent (SNP) | VAF 23/175 reads (13%) | catalogued as COSV100882439; called by muse, mutect2, varscan2
- ZDBF2 | c.5040G>T p.L1680= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV65626810; called by muse, mutect2, varscan2
- ZNF208 | c.1884G>A p.K628= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as rs376576266; called by muse, varscan2
- ZNF304 | c.1473G>T p.V491= | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as COSV99988410; called by muse, mutect2, varscan2
- C16orf82 | c.-20C>G | 5'UTR (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- CDH11 | c.1895-676T>A | Intron (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99217272; called by muse, mutect2, varscan2
- CSF2RA | c.*34_*35insT | 3'UTR (INS) | VAF 49/323 reads (15%) | catalogued as COSV100817473; called by mutect2, pindel, varscan2
- DCAF13 | chr8:103415311 G>T | 5'Flank (SNP) | VAF 14/172 reads (8%) | catalogued as COSV99884203; called by muse, mutect2
- DLG2 | c.205-65738G>T | Intron (SNP) | VAF 52/223 reads (23%) | catalogued as COSV99712756; called by muse, mutect2, varscan2
- FGF13 | c.50-127384G>C | Intron (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- FRMPD2B | n.1072G>T | RNA (SNP) | VAF 16/106 reads (15%) | called by mutect2, varscan2
- MAGEC3 | c.1124-151G>C | Intron (SNP) | VAF 49/120 reads (41%) | catalogued as COSV100024884; called by muse, mutect2, varscan2
- MIR519C | n.36T>A | RNA (SNP) | VAF 43/269 reads (16%) | called by muse, mutect2, varscan2
- MORF4 | n.758C>A | RNA (SNP) | VAF 29/300 reads (10%) | called by muse, mutect2, varscan2
- RALGAPA1 | c.*83G>C | 3'UTR (SNP) | VAF 42/221 reads (19%) | catalogued as COSV51897659, COSV99353354; called by muse, mutect2, varscan2
- SNORD115-43 | n.75T>A | RNA (SNP) | VAF 79/501 reads (16%) | called by muse, mutect2, varscan2
- USP34 | chr2:61185601 A>G | 3'Flank (SNP) | VAF 31/151 reads (21%) | called by muse, mutect2, varscan2
